Surgical pathology report (de-identified scan), TCGA case TCGA-MU-A5YI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Minnesota, specimen TCGA-MU-A5YI-01A (Primary Tumor).

[page 1 of 5]
Collected:

Received:

Reported:

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C53.9
JW 4/29/13

SPECIMEN(S):

A: Left pelvic lymph nodes

B: Right pelvic lymph nodes

C: Right periaortic lymph nodes

D: Uterus, cervix, upper vagina, bilateral tubes and ovaries

FINAL DIAGNOSIS:

A. Lymph nodes, left pelvic, resection:

- No evidence of malignancy (0/10).

B. Lymph nodes, right pelvic, resection:

No evidence of malignancy (0/7).

C. Lymph nodes, right periaortic, resection:

No evidence of malignancy (0/1).

D. Uterus, upper vagina, bilateral tubes and ovaries, hysterectomy and

bilateral salpingo-oophorectomy:

- Uterus:
- Squamous cell carcinoma of the cervix, moderately

differentiated.

[page 2 of 5]
- Tumor involves all quadrants.
- Tumor invades to a maximal depth of 0.71 cm, 1.1 cm

cervical wall thickness.

- Lymphovascular invasion present.
- Surgical margins free of tumor.
- Leiomyomas.
- Inactive endometrium.
- Parametria:
- No evidence of malignancy.
- Fallopian tubes:
- No pathologic changes.
- Ovaries:
- Epithelial inclusion cyst.
- No evidence of metastasis.

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

year-old female with postmenopausal bleeding, with colposcopy showing invasive squamous cell carcinoma.

GROSS:

[page 3 of 5]
Four specimens are received, each labeled with the patient's name and hospital number.

A. Specimen A is designated "left pelvic lymph nodes." The specimen consists of multiple fragments of tan/yellow slightly firm tissue measuring 4.5 x 3 x 0.2 cm in aggregate. Sectioning reveals one possible lymph node measuring 1 cm in greatest dimension. The specimen is submitted in four cassettes.

B. Specimen B is designated "right pelvic lymph nodes." The specimen consists of multiple fragments of yellow/brown slightly firm tissue measuring 5.5 x 4 x 1.5 cm in aggregate. Sectioning reveals multiple possible lymph nodes measuring up to 2.5 cm in greatest dimension. The specimen is submitted in four cassettes.

C. Specimen C is designated "right periaortic lymph node." The specimen consists of a 2.5 x 1.5 x 0.5 cm tan/yellow slightly firm tissue fragment. Sectioning reveals one possible lymph node. The specimen is entirely submitted in one cassette.

D. Specimen D is designated "uterus, cervix, upper vagina, bilateral tubes and ovaries." The specimen consists of a 134 gram hysterectomy specimen with bilateral salpingo-oophorectomy. The uterus with attached cervix measures 7.3 x 6.1 x 2.3 cm. The right ovary measures 2.5 x 2.0 x 1.0 cm and the right fallopian tube measures 5.0 x

[page 4 of 5]
0.5 cm. The left ovary measures 2.0 x 2.0 x 1.1 cm and the left fallopian tube measures 5.0 x 0.5 cm. The cervix measures 4.0 x 3.0 cm and there is a cusp of vaginal mucosa measuring 0.5 cm. The cervical os is patent and measures up to 1 cm. There is a circumferential red/brown ulcerated mass surrounding the cervical os which on sectioning measures 1.2 x 1.2 x 1.0 cm and is located 1.0 cm to the ectocervical margin. The serosa of the uterus is tan/brown, glistening and with multiple subserosal nodules measuring up to 0.7 cm in greatest dimension. The endometrial canal measures 2.5 cm in length. The endometrium is tan/brown and measures up to 0.1 cm in thickness. The anterior myometrium is tan/brown, trabecular and measures up to 1.5 cm in thickness. Sectioning reveals a subserosal white whorled nodule measuring 0.5 cm in greatest dimension, as well as an intramural white whorled nodule which measures 0.6 cm in greatest dimension. The posterior myometrium is red/brown with focal brown softened areas and measures up to 1.7 cm in thickness. The left fallopian tube is tan/brown and glistening. The left ovary is yellow/tan and on sectioning reveals multiple cysts measuring up to 1 cm in greatest dimension. The right possible fallopian tube is tan/brown and glistening. The right ovary is yellow/tan and on cut section reveals multiple cysts which measure up to 0.5 cm in greatest dimension. The specimen is inked as follows: ectocervical margin - blue and serosal margin - black. Representative sections are submitted in 35 cassettes.

Summary of Sections:

[page 5 of 5]
A1- one possible lymph node, bisected.

A2-A4 - remainder of specimen.

B1 - two possible lymph nodes, both bisected, one inked black.

B2 - three possible lymph nodes, largest bisected and inked black.

B3 - one possible lymph node, bisected.

B4 - one possible lymph node, trisected.

C - right periaortic lymph node.

D1-D5 - cervix, 12-3 o'clock.

D6-D11 - cervix, 3-6 o'clock.

D12-D20 - cervix, 6-9 o'clock.

D21-D26 - cervix, 9-12 o'clock.

D27 - left parametrium.

D28 - right parametrium.

D29 - anterior lower uterine segment.

D30 - posterior lower uterine segment.

D31 - anterior myometrium with subserosal nodule.

D32 - anterior endomyometrium with intramural nodule.

D33 - posterior endomyometrium.

D34 - left fallopian tube and ovary.

D35 - right fallopian tube and ovary.

MICROSCOPIC:

Microscopic examination is performed.

Source: NCI Genomic Data Commons file c77b7413-6aff-4252-bd5f-af8ed2d0b43f (TCGA-MU-A5YI.A762F957-1504-4FD5-9862-D7C8DD94A693.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).